Surgical pathology report (de-identified scan), TCGA case TCGA-NF-A5CP, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-NF-A5CP-01A (Primary Tumor).

ICD6-B

Carcinosarcoma / Mixed Mullerian
Tumor, malignant 8950/3
Site: Path-Endometrium C54.1
CCF-Uterus NOS C55.9
9/22/19 11.3

DIAGNOSIS:

Uterus, endometrium, curettage: High grade carcinosarcoma

Uterus, hysterectomy: Invasive high grade carcinosarcoma (malignant mixed Mullerian tumor) forms a necrotic mass (9.5 x 9.0 x 3.5 cm) that fills the endometrial cavity and invades the lower uterine segment and the cervical canal. The tumor invades 2.5 cm into the myometrium (total myometrial thickness, 2.5 cm). Angiolymphatic invasion identified. Focal superficial invasion of the stromal connective tissue of the cervix is present. A calcified subserosal leiomyoma (7.0 x 6.0 x 5.0 cm) is identified.

PRELIMINARY FROZEN SECTION CONSULTATION:

Uterus, endometrium, curettage: High grade carcinoma, likely serous vs. carcinosarcoma. Hold over to classify on permanent sections.

Source: NCI Genomic Data Commons file 1375ee01-887f-4a74-b42e-46463bcc0892 (TCGA-NF-A5CP.030AF2D0-D3BA-4F61-8AA9-95701F8E43CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).